Somatic mutation profile of tumor specimen TARGET-20-PASDXR-04A (aliquot TARGET-20-PASDXR-04A-01D) from TARGET case TARGET-20-PASDXR, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.4 years (3,440 days).
Specimen TARGET-20-PASDXR-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e49cf88-0b03-4672-a081-03b606a1f008.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASDXR-14A (Bone Marrow Normal), aliquot TARGET-20-PASDXR-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7562a683-b72e-42b1-909d-69ac9aed1225

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX1 | c.600dup p.L201Tfs*33 (on ENST00000344691 / NM_001001890.3; = p.L228Tfs*33 on NM_001754.5) | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel, varscan2
